Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HQ, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HQ-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell
Keratinizing NOS 8071/3
Site: Lung, middle lobe C34.2
gid 2/1/13

Synoptic translated report

Site : Right lung / middle lobe

☒ Central ☐ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 5.3 x 4.0 x 3.0 cm

Visceral pleural invasion: ☒ Yes ☐ No ☐ NA

Chest wall invasion : ☐ Yes ☒ No ☐ NA

Histological diagnosis : Well to moderately differentiated keratinizing squamous cell carcinoma

Node status : N2 (8/28)

TNM : pT3 (pericardial invasion) N2 (8/28) G2 R0

Pathologist signature:

Date:

HPV A Discrepancy		
Prior T. Relapse History		
Local Synchronous Primary Nodules		
Cases (circle):		
Re-review Initials:		

1/24/13

Source: NCI Genomic Data Commons file b403a745-50d2-477c-bafe-ea0e443b9331 (TCGA-NC-A5HQ.A4B5AAFA-D22F-4DA0-A4ED-54630EF8156F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).